Somatic mutation profile of tumor specimen BA2960D (aliquot aq-BA2960D) from BEATAML1.0 case 2252, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.6 years (29,086 days).
Specimen BA2960D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0d21a45-f828-4dd6-9613-c77099eb5541.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2917D (Solid Tissue Normal), aliquot aq-BA2917D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43fe643c-be3a-4621-a4b6-d5c60e19320b

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 79/167 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATG13 | c.294A>G p.I98M | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1233823301; called by muse, mutect2, varscan2
- G3BP1 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 55/58 reads (95%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs781702756; called by muse, mutect2, varscan2
- LAMA5 | c.4717C>T p.R1573C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs146565862; called by muse, mutect2, varscan2
- PHF6 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99045875; called by muse, mutect2, varscan2
- ZNF500 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1421914870; called by muse, mutect2
- THOC5 | c.1503del p.P502Qfs*19 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
